Somatic mutation profile of tumor specimen MP2PRT-PAUIPV-TMP1-A (aliquot MP2PRT-PAUIPV-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUIPV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,095 days).
Specimen MP2PRT-PAUIPV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8d92d00-c59f-49ec-ba7b-a924291013a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIPV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIPV-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d5bb3a0-2174-4473-b584-2caa71bed40f

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 30, Silent 15, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX41 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 22/370 reads (6%) | catalogued as rs754907965, COSV57904739; called by muse, mutect2
- DPH6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1156669248, COSV56612103; called by muse, mutect2
- DTHD1 | c.1801G>C p.E601Q (on ENST00000456874; = p.E436Q on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100678194; called by muse, mutect2
- H3C2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 28/529 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2
- HHLA1 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV70154281; called by muse, mutect2
- HJURP | c.1489T>G p.L497V | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs780858904; called by muse, mutect2
- HMBS | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.113); catalogued as CM022212; called by muse, mutect2
- HOXA3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 47/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825391; called by muse, mutect2, varscan2
- LMNTD2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 59/591 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374252641; called by muse, mutect2
- MROH7 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 83/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs374919113; called by muse, mutect2, varscan2
- OR5P3 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 27/618 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs765176028; called by muse, mutect2
- PCDHA3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63538638; called by muse, mutect2, varscan2
- SLC45A1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs770745558, COSV57098712; called by muse, mutect2, varscan2
- SPDEF | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148079586, COSV55058369; called by muse, mutect2, varscan2
- AQP3 | c.360del p.F120Lfs*38 | Frame Shift Del (DEL) | VAF 50/248 reads (20%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- CDC42BPB | c.3829G>A p.D1277N | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CXCL10 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.096); called by mutect2, varscan2
- DNMT3A | c.2614G>T p.V872F | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ERICH5 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.844); called by muse, mutect2
- GPR161 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 29/535 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.59); called by muse, mutect2
- GRIN2A | c.1003C>G p.H335D | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- KIF13A | c.2790+1G>A p.X930_splice | Splice Site (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- LINGO2 | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MEI4 | c.25A>G p.R9G | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NT5C1B | c.873G>C p.E291D (on ENST00000359846 / NM_001199086.2; = p.E231D on NM_033253.4) | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); called by muse, mutect2
- OR6A2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2
- QPRT | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2
- RADX | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- RNF25 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO1 | c.4198G>A p.D1400N | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- SLC5A8 | c.1316C>G p.S439* | Nonsense Mutation (SNP) | VAF 14/322 reads (4%) | called by muse, mutect2
- TRIM33 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 20/581 reads (3%) | called by muse, mutect2
- UGT2B17 | c.1111G>C p.A371P | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF2 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 13/343 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2
- ACE | c.1890G>A p.P630= | Silent (SNP) | VAF 27/443 reads (6%) | catalogued as rs769674897; called by muse, mutect2
- ALPK3 | c.2904G>T p.L968= | Silent (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- CAVIN2 | c.1014C>T p.S338= | Silent (SNP) | VAF 28/391 reads (7%) | catalogued as rs760404586, COSV58425183; called by muse, mutect2
- CLEC7A | c.294A>G p.S98= | Silent (SNP) | VAF 67/302 reads (22%) | called by muse, mutect2, varscan2
- FLNA | c.6018C>T p.H2006= (on ENST00000369850 / NM_001110556.2; = p.H1998= on NM_001456.3) | Silent (SNP) | VAF 72/424 reads (17%) | catalogued as rs1557176187, COSV61037457; called by muse, mutect2, varscan2
- FOXD4L3 | c.171G>A p.P57= | Silent (SNP) | VAF 45/413 reads (11%) | catalogued as rs1413562170; called by muse, mutect2, varscan2
- IGLV4-69 | c.357T>A p.I119= | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2
- IGLV4-69 | c.359A>C p.*120= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs759363255; called by muse, mutect2
- OR8J3 | c.63A>G p.P21= | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2, varscan2
- PPP4R3C | c.183C>G p.P61= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as COSV69081061; called by muse, mutect2
- PTPRD | c.1389C>G p.V463= | Silent (SNP) | VAF 26/454 reads (6%) | catalogued as COSV61928092; called by muse, mutect2
- SLC5A5 | c.1176C>A p.L392= | Silent (SNP) | VAF 18/363 reads (5%) | catalogued as COSV55832302; called by muse, mutect2
- SLIT3 | c.3393G>C p.G1131= | Silent (SNP) | VAF 23/496 reads (5%) | called by muse, mutect2
- TBXA2R | c.420C>A p.R140= | Silent (SNP) | VAF 48/669 reads (7%) | catalogued as COSV64344493; called by muse, mutect2
- TDRD6 | c.417C>T p.C139= | Silent (SNP) | VAF 124/531 reads (23%) | catalogued as rs752645493, COSV60173957; called by muse, mutect2, varscan2
